Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A3IQ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A3IQ-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB: (Age)

Gender: M

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

INPATIENT

Clinical Diagnosis & History:

Bladder cancer (HG T2 UC)

Specimens Submitted:

- 1: Urethral margin (fs)
- 2: Left pelvic lymph nodes
- 3: Bladder, prostate and seminal vesicles
- 4: Left ureter
- 5: Distal right native ureter

DIAGNOSIS:

1. Urethral margin, biopsy:

- Benign urothelial and prostatic tissue

2. Left pelvic lymph nodes:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 14

ICA-0-3
carcinoma, urothelial, NOS 8120/3
Site: bladder, wall, posterior 667.4
fw
12/8/11

3. Bladder, prostate and seminal vesicles:

Tumor Type:

Urothelial carcinoma with mixed histologic features, including: NOS, nested and plasmacytoid/signet ring cell features

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Papillary and flat

Pattern of growth of the Invasive component:

Diffuse and infiltrating

Tumor Multicentricity:

Multiple foci of carcinoma in situ are identified

Bladder Local Invasion:

Perivesical soft tissues

Extravesical Tumor Extension:

Left ureter involved

Urethra involved

Left ureter involved at the left orifice by in situ carcinoma; urethra and peri-urethral ducts involved by carcinoma in situ

	fw 12/8/11	

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Vascular Invasion:
Identified

Perineural Invasion:
Identified

Surgical Margins:
Free of tumor

Non-Neoplastic Mucosa:
Exhibiting ulceration
Exhibiting foreign body reaction

Prostate:
Nodular hyperplasia
Other Extensive acute and chronic inflammation, High-grade prostatic intraepithelial neoplasia

Seminal Vesicles:
Not involved

Perivesical Lymph Nodes:
Not identified

The Pathologic Stage is (AJCC 2002):
pT3 (Invasion of perivesicle soft tissue)

PRIs (Involvement of urethra or prostatic ducts without stromal invasion) stromal invasion)

4. Left ureter; excision:

- Benign segment of ureter

5. Distal right native ureter; excision:

- Benign segment of ureter, with focal acute inflammation

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	

Gross Description:

1. The specimen is received fresh, labeled "urethral margin", and consists of a fragment of yellow tan soft tissue measuring 2.5 x 0.7 x 0.5 cm. The specimen is entirely frozen.

Summary of sections:
FSC – frozen section control

2. The specimen is received in formalin, labeled "left pelvic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.2 to 1.2 cm in greatest dimension. All identified lymph nodes are submitted (specimen submitted for lymph node dissection).

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

Summary of sections:

LN - lymph nodes

BLN - bisected lymph nodes

3. The specimen is received fresh, labeled "Bladder, prostate and seminal vesicles". It consists of a bladder measuring 7 cm from superior to inferior, 5 cm laterally and 4 cm from anterior to posterior. The left aspect of the bladder and prostate is inked blue and the right aspect is inked green. The prostatic urethral margin is shaved and submitted. The bladder is opened along the anterior midline to reveal an ulcerated area measuring 3 x 2 cm which is grossly situated within the right posterior / lateral wall. The ulceration is located 2.5 cm from the left orifice and 0.7 from the right. Both ureters are probe patent measuring up to 0.2 cm in maximum diameter. The lesion is sectioned to reveal that the ulceration is limited to the mucosa with underlying dense fibrosis, extending to the peri-vesical fat. The remaining bladder mucosa is unremarkable. Perivesical adipose tissue is submitted for lymph node dissection and possible discrete perivesical lymph nodes are grossly not identified. The prostate is serially sectioned to reveal a multinodular cut section. Representative sections are submitted including three sections from each prostatic quadrant and transition zone. The specimen is photographed.
- ` submitted.

Summary of sections:

UTHM - urethral margin

RUM - right ureter margin

LUM - left ureter margin

RUO - right ureter orifice

LUO - left ureter orifice

L- ulcerated lesion, entirely sequentially submitted from right posterior to right lateral

LP - left posterior wall

LA - left anterior wall

RP - right posterior wall

RA - right anterior wall

TRI - trigone

DOM - dome

F - perivesical fat

RSV - right seminal vesicle

LSV - left seminal vesicle

RAP - right apex prostate

LAP - left apex prostate

RAM - right anterior mid prostate

RPM - right posterior mid prostate

LAM - left anterior mid prostate

LPM - left posterior mid prostate

RAB - right anterior base prostate

RPB - right posterior base prostate

LAB - left anterior base prostate

LPB - left posterior base prostate

PLN- possible lymphoid tissue

4). The specimen is received in formalin labeled "left ureter" and consists of an unoriented 8.5 X 0.4 cm gray-white smooth portion of ureter with attached fatty tissue. The specimen is sectioned to reveal a 0.1cm lumen. No discrete lesions or gross abnormalities are identified. Representative sections to include both margins are submitted.

Summary of sections:

M- margin

SS- central sequential sections

M2- opposing margin

5). The specimen is received in formalin labeled "distal right native ureter" and consists of a 0.7 x 0.4 x 0.4 cm clipped gray-white soft tissue with attached fatty tissue. The specimen is sectioned to reveal a 0.1 cm possible lumen. The specimen is submitted in its entirety.

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

Summary of sections:
U - undesignated

Summary of Sections:

Part 1: Urethral margin (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 2: Left pelvic lymph nodes

Block	Sect. Site	PCs
4	LN	4

Part 3: Bladder, prostate and seminal vesicles

Block	Sect. Site	PCs
1	DOM	1
1	F	1
9	L	9
1	LA	1
1	LAB	1
1	LAM	1
1	LAP	1
1	LP	1
1	LPB	1
1	LPM	1
1	LSV	1
1	LUM	1
1	LUO	1
2	PLN	2
1	RA	1
1	RAB	1
1	RAM	1
1	RAP	1
1	RP	1
1	RPB	1
1	RPM	1
1	RSV	1
1	RUM	1
1	RUO	1
1	TRI	1
1	UTHM	1

Part 4: Left ureter

Block	Sect. Site	PCs
1	M	1
1	M2	1
2	SS	2

Part 5: Distal right native ureter

Block	Sect. Site	PCs
2	U	2

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Urethral margin (fs): Benign
Permanent diagnosis: Same

Source: NCI Genomic Data Commons file fb15eff9-6dbd-48cc-9dd4-a6d4eaf86af5 (TCGA-DK-A3IQ.11C9802C-072A-4B09-96FB-0CAC21BF43D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).